Somatic mutation profile of tumor specimen TCGA-12-1598-01A (aliquot TCGA-12-1598-01A-01W-0643-08) from TCGA case TCGA-12-1598, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.9 years (27,730 days).
Specimen TCGA-12-1598-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d00e425-a7b6-43ee-a9a0-685c43d60b50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-1598-10A (Blood Derived Normal), aliquot TCGA-12-1598-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b586a5f4-47f0-4583-b725-4076fde0efc9

The open-access MAF lists 60 somatic variants for this specimen: 51 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 46, Silent 9, Frame Shift Del 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.204C>G p.Y68* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | hotspot (GDC flag); catalogued as rs773176120, CM110140, COSV64297713; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 65/87 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV101125350; called by muse, mutect2, varscan2
- ANKRD17 | c.7445C>T p.P2482L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.021); catalogued as COSV100429888; called by muse, mutect2
- ARHGAP28 | c.1465G>A p.V489I (on ENST00000383472 / NM_001366230.1; = p.V330I on NM_001010000.3) | Missense Mutation (SNP) | VAF 88/230 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs749070329, COSV51634680; called by muse, mutect2, varscan2
- ARHGEF9 | c.611C>A p.A204D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492336; called by muse, mutect2, varscan2
- ARNTL2 | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 265/567 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV99668041; called by muse, mutect2, varscan2
- BCOR | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1177018779, COSV100654023; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC113 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs923923731, COSV99541191; called by muse, mutect2, varscan2
- CDH17 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs569997084, COSV50325476, COSV50337417; called by muse, mutect2, varscan2
- CEMIP2 | c.3461T>A p.I1154N | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100987501; called by muse, mutect2
- CENPN | c.440A>G p.Y147C | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100001594; called by muse, mutect2, varscan2
- CFAP77 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs745530694, COSV100546098; called by muse, mutect2, varscan2
- COL14A1 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.287); catalogued as COSV99920487; called by muse, mutect2, varscan2
- DNAJC19 | c.128C>G p.S43C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV101230753; called by muse, mutect2
- ECE1 | c.606G>T p.L202F | Missense Mutation (SNP) | VAF 104/306 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV99942276; called by muse, mutect2, varscan2
- ELOVL7 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764734594, COSV70917503; called by muse, mutect2, varscan2
- FAT2 | c.10804G>A p.V3602I | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs549157480, COSV55823482; called by muse, mutect2, varscan2
- FCRL5 | c.2896G>A p.G966R | Missense Mutation (SNP) | VAF 59/77 reads (77%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs377397519; called by muse, mutect2, varscan2
- FTSJ3 | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV100835052; called by muse, mutect2, varscan2
- HLA-DOA | c.212T>A p.L71Q | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100008345; called by muse, mutect2, varscan2
- LDB3 | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764571838, COSV99555836; called by muse, mutect2, varscan2
- LRP1B | c.11213G>A p.G3738E | Missense Mutation (SNP) | VAF 253/525 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101260221, COSV67257432; called by muse, mutect2, varscan2
- MAP4K3 | c.2680T>G p.Y894D | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99811026; called by muse, mutect2, varscan2
- MCMDC2 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 73/151 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100552286; called by muse, mutect2, varscan2
- MYH7B | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs1190716212, COSV53418992; called by muse, mutect2
- NETO1 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV55017419; called by muse, mutect2
- NFIB | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101100352; called by muse, mutect2
- NFIB | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101100354; called by muse, mutect2
- NIPBL | c.2546C>G p.S849C | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.439); catalogued as rs746596330, COSV99242407; called by muse, mutect2
- NKTR | c.2356G>A p.V786I | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99236273; called by muse, mutect2, varscan2
- OPRPN | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.036); catalogued as COSV101271104, COSV68192645; called by muse, mutect2, varscan2
- OR2D3 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as COSV99549891; called by muse, mutect2, varscan2
- OR2T27 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 134/438 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs757391223, COSV100788324, COSV61281501, COSV61283032; called by muse, mutect2, varscan2
- OR5D13 | c.373T>A p.F125I | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV100687019; called by muse, mutect2, varscan2
- OR7D2 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 30/303 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV100713071; called by muse, mutect2
- P2RY13 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 115/245 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV56369321; called by muse, mutect2, varscan2
- PAX3 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as COSV100398904, COSV100399936; called by muse, mutect2, varscan2
- PDGFC | c.173T>C p.I58T | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1214202962, COSV99926105; called by muse, mutect2, varscan2
- PGBD1 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV99460868; called by muse, mutect2
- PHKA2 | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101177412, COSV101177639; called by muse, mutect2
- PRAMEF4 | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 108/482 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs754770732, COSV99340171; called by muse, mutect2, varscan2
- SETD2 | c.4547G>A p.C1516Y | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57441296, COSV57443398, COSV57448602; called by muse, mutect2, varscan2
- SLC17A5 | c.1303A>G p.I435V | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.794); catalogued as COSV100867151; called by muse, mutect2, varscan2
- TEC | c.939C>A p.Y313* | Nonsense Mutation (SNP) | VAF 76/213 reads (36%) | catalogued as COSV100797969; called by muse, mutect2, varscan2
- TMPRSS15 | c.2360G>C p.G787A | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99519182; called by muse, mutect2, varscan2
- TMUB2 | c.866G>A p.R289Q (on ENST00000538716 / NM_001353177.2; = p.R269Q on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as rs764813246, COSV100116318; called by muse, mutect2, varscan2
- CRNKL1 | c.2149_2150del p.Q717Vfs*2 | Frame Shift Del (DEL) | VAF 75/196 reads (38%) | called by mutect2, pindel, varscan2
- EPHA8 | c.2735del p.P912Hfs*54 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | called by mutect2, pindel, varscan2
- FCGBP | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SULF2 | c.1767_1770del p.D590Tfs*9 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel
- ATP8B4 | c.3006G>A p.L1002= | Silent (SNP) | VAF 43/201 reads (21%) | catalogued as rs1314874797, COSV99467223; called by muse, mutect2, varscan2
- CRYBG2 | c.3187C>T p.L1063= | Silent (SNP) | VAF 56/96 reads (58%) | catalogued as COSV100366956, COSV57490869; called by muse, mutect2, varscan2
- IRS4 | c.1572C>T p.G524= | Silent (SNP) | VAF 17/183 reads (9%) | catalogued as COSV100929696; called by muse, mutect2
- MAGEB6 | c.597G>A p.A199= | Silent (SNP) | VAF 11/186 reads (6%) | catalogued as rs370599063, COSV66871971; called by muse, mutect2
- MORC4 | c.1726C>A p.R576= | Silent (SNP) | VAF 38/272 reads (14%) | catalogued as COSV55239974, COSV99717567; called by muse, mutect2, varscan2
- SERPINE1 | c.1047C>T p.I349= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs756724814, COSV56170114, COSV99776831; called by muse, mutect2
- SUSD4 | c.957G>A p.T319= | Silent (SNP) | VAF 55/77 reads (71%) | catalogued as rs1310714877, COSV59554520; called by muse, mutect2, varscan2
- ZNF641 | c.660G>A p.P220= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as rs142149116; called by muse, mutect2, varscan2
- ZNF695 | c.237A>G p.T79= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV100377694; called by muse, mutect2, varscan2
